Gene-level copy-number profile of tumor specimen TCGA-FB-AAPZ-01A from TCGA case TCGA-FB-AAPZ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.3 years (19,847 days).
Specimen TCGA-FB-AAPZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.53840195-91c2-4788-bffd-1329576ea435.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FB-AAPZ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67412f79-6ddb-4e9e-afef-fe8797c049da

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 271; copy number 1: 793; copy number 2: 17,292; copy number 3: 20,409; copy number 4: 18,134; copy number 5: 1,939; copy number 6: 750; copy number 7: 147; copy number 8: 53; copy number 11: 13; copy number 12: 2; copy number 13: 10; copy number 18: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FB-AAPZ-01A-11D-A40V-01): tumor purity 0.71, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:135,859,369–138,083,657, 10 genes: LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1.
- chr9:20,532,552–27,543,902, 107 genes (broad region; genes not listed).
- chr17:11,241,213–11,564,063, 1 gene (within-gene range 0–2): SHISA6.
- chr17:11,598,470–12,395,177, 11 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1.
- chr18:5,310,396–6,108,382, 10 genes (within-gene range 0–2): AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–6,017,839, 2 genes: AP001021.2, RNU5F-3P.
- chr18:30,298,910–30,298,960, 1 gene: MIR302F.
- chr18:50,967,991–53,629,990, 22 genes: ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 231 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:118,620,498–119,325,265, 10 genes, copy number 13 (within-gene range 5–13): SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr8:122,977,026–135,742,495, 206 genes, copy number 7–11 (broad region; genes not listed).
- chr9:27,535,640–29,826,711, 15 genes, copy number 7–18 (within-gene range 0–18): C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.

Autosomal genes at a single copy (total copy number 1): 793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
